CCDI case PBBSUA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/f542eb49-251a-498e-9ced-b225689aa71a

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 18.8 years (6,851 days).

Biospecimens (3 samples)
- Sample 0DG84M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG855: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG87Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
